TCGA case TCGA-AG-A023 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3bc6e336-f58e-4dc4-8414-7318e55016ed

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 62 years; Vital status: Dead; Days to death: 1,581 days (4.3 years).

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 62.5 years (22,830 days); Year of diagnosis: 2005; AJCC staging edition: 5th; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 1,581 days (4.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 12; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC).
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 64.8 years (23,652 days); Days to diagnosis: 822 days (2.3 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 61 days; Disease response: With Tumor.
- Day 822 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,581 days (4.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 1.88 ng/mL.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-A023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 410 mg.
  Slide TCGA-AG-A023-01A-01-MS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 65; Percent normal cells: 45; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
  Slide TCGA-AG-A023-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 8; Percent necrosis: 1; Percent stromal cells: 6; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-AG-A023-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AG-A023-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 1.88; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: malignant neoplasm of breast unspecified.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -1096.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: unknown treatment history.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,581 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,581 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 822 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AG-A023-01): tumor purity 0.55, ploidy 2.12, whole-genome doublings 0 (call status: legacy_call).
